TCGA case TCGA-G8-6909 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a468e725-ad4b-411d-ac5c-2eacc68ec580

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 3,553 days (9.7 years).

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C77.1; Tissue or organ of origin: Intrathoracic lymph nodes; Site of resection or biopsy: Intrathoracic lymph nodes; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,661 days); Year of diagnosis: 2002; AJCC staging edition: 5th; Ann Arbor clinical stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,553 days (9.7 years); Ann Arbor extranodal involvement: No; Sites of involvement: Lymph Node, Mediastinal.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Pegylated Liposomal Doxorubicin Hydrochloride + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21 + Doxil; Days to treatment start: 25 days; Days to treatment end: 129 days; Number of cycles: 6.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.

Follow-up (4 entries)
- Days to follow up: 3,227 days (8.8 years); Disease response: Tumor Free.
- Days to follow up: 3,553 days (9.7 years); Disease response: Tumor Free.
- ECOG performance status: 0.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Negative.
- CD10 (IHC): Negative.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD30 (IHC): Negative.
- CD5 (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 90.5 kg; Height: 178 cm; BMI: 28.6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G8-6909-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.4; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-G8-6909-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 95; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G8-6909-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G8-6909-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: mediastinal.
- Primary pathology: Extranodal site involvement: 0.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: Pet scan after treatment results: Not Done; Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP-21 + Rituximab + Doxil.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxil; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP-21 + Rituximab + Doxil.
- Drug treatment 3: Pharmaceutical therapy drug name: Adriamycin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP-21 + Rituximab + Doxil.
- Drug treatment 6: Pharmaceutical therapy drug name: Cytoxan; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP-21 + Rituximab + Doxil.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,553 days; disease-specific survival: no event (censored), 3,553 days; disease-free interval: no event (censored), 3,553 days; progression-free interval: no event (censored), 3,553 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G8-6909-01A-11D-2209-01): tumor purity 0.52, ploidy 2.14, whole-genome doublings 0.
